Somatic mutation profile of tumor specimen 0DUNPE from CCDI case PBCLEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.2 years (5,192 days).
Specimen 0DUNPE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 952b0822-37d7-4149-a61f-84929a62fe14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUNP0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4da478f7-0100-4516-9803-2892840bc73d

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, 3'UTR 2, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR2L13 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs377126567, COSV63557537; called by muse, mutect2, varscan2
- POTEE | c.2057dup p.N687Efs*2 | Frame Shift Ins (INS) | VAF 27/175 reads (15%) | catalogued as rs772047281; called by mutect2, varscan2
- SECISBP2L | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773689714, COSV55933601, COSV55934517; called by muse, mutect2, varscan2
- STX1A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs782606855; called by mutect2, varscan2
- CDC73 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- CRB1 | c.780A>C p.E260D | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- FBRSL1 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FCGBP | c.4150C>G p.Q1384E | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FMOD | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- GK5 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- GOLGA6L10 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- GRID2IP | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MED13 | c.4130A>G p.E1377G | Missense Mutation (SNP) | VAF 90/442 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- OR52E4 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2
- PDZD8 | c.1840G>T p.V614F | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PHACTR3 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TENM2 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- TYK2 | c.3047C>T p.A1016V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZBTB33 | c.1851T>A p.Y617* | Nonsense Mutation (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- ZNF350 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ZSWIM6 | c.2926C>G p.L976V | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASXL3 | c.4330C>A p.R1444= | Silent (SNP) | VAF 11/226 reads (5%) | catalogued as CM1514543, COSV52473481; called by muse, mutect2
- PCDHA2 | c.1365C>T p.F455= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as COSV65370460; called by muse, mutect2, varscan2
- PER1 | c.1053C>A p.P351= | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- RIMBP2 | c.1923G>A p.P641= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs565981416, COSV55474314; called by muse, mutect2, varscan2
- RNF133 | c.984C>T p.T328= | Silent (SNP) | VAF 27/310 reads (9%) | called by muse, mutect2
- SLC6A2 | c.1452T>G p.A484= | Silent (SNP) | VAF 63/179 reads (35%) | called by muse, mutect2, varscan2
- XIRP2 | c.3816C>A p.G1272= (on ENST00000628543; = p.G1447= on NM_152381.6) | Silent (SNP) | VAF 78/266 reads (29%) | catalogued as rs1329222323; called by muse, mutect2, varscan2
- CAVIN2 | c.*42C>A | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- MUC19 | n.11039A>T | RNA (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- OR4K17 | c.*28C>A | 3'UTR (SNP) | VAF 12/171 reads (7%) | catalogued as rs1207880599; called by muse, mutect2
- PDE4C | c.596-64C>T | Intron (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SIX3 | c.-80del | 5'UTR (DEL) | VAF 4/29 reads (14%) | called by mutect2, varscan2
